CPTAC case C3L-00086 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/477d73a2-9776-46fb-9075-5d62e8cda29b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Dead; Days to death: 1,578 days (4.3 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 56.9 years (20,790 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,578 days (4.3 years); Progression or recurrence: yes; Days to last follow up: 1,578 days (4.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm (a second GDC size field records 2.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 330 days; Disease response: Tumor Free.
- Days to follow up: 701 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,046 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,436 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,578 days (4.3 years); Disease response: With Tumor.
- Days to follow up: 1,578 days (4.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 580 days (1.6 years).

Other clinical attributes
- Weight: 80 kg; Height: 165 cm; BMI: 29.38.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 4; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00086-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 301 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00086-21: Section location: Both Anterior and Posterior Endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-00086-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 401 mg.
- Sample C3L-00086-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
